Somatic mutation profile of tumor specimen TCGA-EM-A3OB-01A (aliquot TCGA-EM-A3OB-01A-11D-A21Z-08) from TCGA case TCGA-EM-A3OB, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 33.6 years (12,282 days).
Specimen TCGA-EM-A3OB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3fe40628-5498-4f9d-993a-192f8ee92d21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A3OB-10A (Blood Derived Normal), aliquot TCGA-EM-A3OB-10A-01D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc0052b1-e602-4f2c-b45f-186e60dd34b6

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 104/233 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AMDHD1 | c.778C>T p.H260Y | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1266737959, COSV57138864, COSV57139422; called by muse, mutect2
- COL5A3 | c.826C>A p.P276T | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV53410872; called by muse, mutect2
- IQSEC2 | c.3070T>A p.S1024T (on ENST00000642864 / NM_001111125.3; = p.S819T on NM_015075.2) | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as COSV64725593; called by muse, mutect2, varscan2
- UTP3 | c.1231A>G p.I411V | Missense Mutation (SNP) | VAF 54/116 reads (47%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.841); catalogued as rs376767606, COSV54661121; called by muse, mutect2, varscan2
- IGHD4-11 | c.15A>G p.L5= | Silent (SNP) | VAF 61/226 reads (27%) | called by muse, mutect2, varscan2
- WRAP53 | c.846G>A p.S282= | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as rs34740153; ClinVar: likely benign; called by muse, mutect2, varscan2
